Somatic mutation profile of tumor specimen TCGA-RW-A680-01A (aliquot TCGA-RW-A680-01A-11D-A35D-08) from TCGA case TCGA-RW-A680, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Paraganglioma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Age at diagnosis: 57.5 years (21,010 days).
Specimen TCGA-RW-A680-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0bd8428-26c6-4463-bb8e-9039b8b16a5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A680-10B (Blood Derived Normal), aliquot TCGA-RW-A680-10B-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e902eef-edeb-460f-8e33-537739b6811b

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 8, RNA 1, Intron 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.5657C>T p.P1886L | Missense Mutation (SNP) | VAF 193/514 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64871309, COSV64886002; called by muse, mutect2, varscan2
- DNAH3 | c.11579T>C p.V3860A | Missense Mutation (SNP) | VAF 97/245 reads (40%) | SIFT tolerated (1); PolyPhen possibly damaging (0.672); catalogued as rs1329422203; called by muse, mutect2, varscan2
- GPR132 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779172413; called by muse, mutect2, varscan2
- HCN1 | c.2341C>T p.R781W | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100299291, COSV100303082; called by muse, mutect2, varscan2
- KCNA6 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs781656226, COSV54974189, COSV54975172; called by muse, mutect2, varscan2
- MAGEC1 | c.2830G>T p.G944C | Missense Mutation (SNP) | VAF 119/286 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs757622965, COSV53574213; called by muse, mutect2, varscan2
- RBM12B | c.1552A>G p.I518V | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1432634641; called by muse, mutect2, varscan2
- ABCC10 | c.3769C>T p.P1257S (on ENST00000372530 / NM_001198934.2; = p.P1229S on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/246 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- AURKC | c.104+1G>T p.X35_splice (on ENST00000302804 / NM_001015878.2; = p.X1_splice on NM_003160.3) | Splice Site (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- CD300LB | c.173G>A p.C58Y | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLCN1 | c.578A>T p.E193V | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL24A1 | c.4639G>A p.D1547N | Missense Mutation (SNP) | VAF 64/112 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LEXM | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- OR2J3 | c.608T>C p.M203T | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PREX2 | c.1077A>C p.E359D | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRTG | c.372_389del p.Q125_A130del | In Frame Del (DEL) | VAF 26/171 reads (15%) | called by mutect2, pindel, varscan2
- RPGR | c.1411C>A p.P471T | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2
- SVIL | c.192T>A p.D64E | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- AKAP12 | c.2538G>A p.V846= | Silent (SNP) | VAF 63/156 reads (40%) | called by muse, mutect2, varscan2
- G6PC3 | c.981C>T p.L327= | Silent (SNP) | VAF 16/178 reads (9%) | catalogued as rs752964083; called by muse, mutect2
- KRT74 | c.219C>T p.Y73= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs763517375; called by muse, mutect2, varscan2
- LCA5L | c.1188C>T p.I396= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as rs1238940659, COSV55744422; called by muse, mutect2, varscan2
- POLD2 | c.1335G>C p.L445= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- PPP1R26 | c.105C>T p.D35= | Silent (SNP) | VAF 32/95 reads (34%) | called by muse, mutect2, varscan2
- RBP3 | c.705C>A p.T235= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs1465594455; called by muse, mutect2
- ZAN | c.8070C>T p.S2690= | Silent (SNP) | VAF 35/74 reads (47%) | called by muse, mutect2, varscan2
- OR2W5 | n.413G>T | RNA (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- TBC1D32 | c.2571-9366G>A | Intron (SNP) | VAF 15/66 reads (23%) | catalogued as COSV51541882; called by muse, mutect2, varscan2
